Somatic mutation profile of tumor specimen ALCH-ADTB-TTP1-A (aliquot ALCH-ADTB-TTP1-A-1-0-D-A582-36) from ALCHEMIST case ALCH-ADTB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Large cell neuroendocrine carcinoma; Age at diagnosis: 77.5 years (28,316 days).
Specimen ALCH-ADTB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2cf0b00-df2f-4569-a91e-a0b181f5b0fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADTB-NB1-A (Blood Derived Normal), aliquot ALCH-ADTB-NB1-A-1-0-D-A582-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df09ed1c-3095-40cd-8181-7b7bce251de6

The open-access MAF lists 258 somatic variants for this specimen: 180 protein-altering or splice-affecting, 50 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 152, Silent 50, Nonsense Mutation 16, Intron 11, RNA 7, Splice Site 6, 5'UTR 4, Frame Shift Del 4, 5'Flank 2, Splice Region 2, 3'UTR 2, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 76/246 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.1390C>G p.H464D | Missense Mutation (SNP) | VAF 102/347 reads (29%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV52206493; called by muse, varscan2
- ADGRL3 | c.2533G>T p.V845F (on ENST00000506720 / NM_001322402.2; = p.V777F on NM_015236.6) | Missense Mutation (SNP) | VAF 232/779 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101546923; called by muse, mutect2, varscan2
- AHNAK2 | c.6751C>A p.L2251I | Missense Mutation (SNP) | VAF 128/556 reads (23%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.99); catalogued as rs778944517; called by muse, varscan2
- ALDH2 | c.1471G>T p.G491C | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1489865347; called by muse, mutect2
- ALK | c.2453G>C p.G818A | Missense Mutation (SNP) | VAF 115/486 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV66562971; called by muse, mutect2, varscan2
- ASCC1 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 143/378 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs181007451, COSV100403602, COSV100403885; called by muse, mutect2, varscan2
- ATG4B | c.538+2T>G p.X180_splice | Splice Site (SNP) | VAF 47/206 reads (23%) | catalogued as COSV60350901; called by muse, mutect2, varscan2
- ATP1A4 | c.2590G>A p.G864R | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs925890109; called by muse, mutect2, varscan2
- BAZ2A | c.1867G>C p.E623Q | Missense Mutation (SNP) | VAF 44/235 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51640662; called by muse, mutect2, varscan2
- BRAF | c.728T>G p.F243C | Missense Mutation (SNP) | VAF 215/546 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV56374957; called by muse, mutect2, varscan2
- C21orf91 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 59/308 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1407216362; called by muse, mutect2, varscan2
- CA13 | c.235+1G>T p.X79_splice | Splice Site (SNP) | VAF 76/273 reads (28%) | catalogued as COSV100410136; called by muse, mutect2, varscan2
- CACNA1D | c.1011G>T p.W337C | Missense Mutation (SNP) | VAF 130/459 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55436512; called by muse, mutect2, varscan2
- COL11A2 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 26/766 reads (3%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.865); catalogued as rs768676077, COSV100553700; called by muse, mutect2
- COL4A2 | c.4361A>G p.D1454G | Missense Mutation (SNP) | VAF 55/321 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV64626581; called by muse, mutect2, varscan2
- COL5A1 | c.1666G>T p.A556S | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.679); catalogued as COSV65665609; called by muse, mutect2, varscan2
- CYLC2 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 141/596 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66336385; called by muse, mutect2, varscan2
- DACT1 | c.1408G>A p.G470R | Missense Mutation (SNP) | VAF 94/203 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.216); catalogued as rs749374751; called by muse, mutect2, varscan2
- DDR2 | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 199/1048 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as COSV63372986; called by muse, mutect2, varscan2
- EFHB | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 117/376 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV55554728; called by muse, mutect2, varscan2
- FAM186A | c.2237G>C p.G746A | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.78); catalogued as rs1222657064; called by muse, mutect2, varscan2
- FAT1 | c.8362G>A p.E2788K | Missense Mutation (SNP) | VAF 98/426 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV101499676; called by muse, mutect2, varscan2
- FBXO15 | c.571del p.L191Sfs*6 | Frame Shift Del (DEL) | VAF 61/243 reads (25%) | catalogued as COSV54044866; called by mutect2, pindel
- FOXI1 | c.16C>A p.L6M | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.459); catalogued as COSV60388436; called by muse, mutect2, varscan2
- GABRA2 | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 230/779 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV62911736; called by muse, mutect2, varscan2
- GCN1 | c.6545C>G p.S2182* | Nonsense Mutation (SNP) | VAF 93/564 reads (16%) | catalogued as COSV56104726; called by muse, mutect2, varscan2
- H2AC6 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 51/345 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100019863, COSV58417094; called by muse, mutect2, varscan2
- KCTD20 | c.470G>T p.R157L | Missense Mutation (SNP) | VAF 135/219 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99536343; called by muse, mutect2, varscan2
- KRTAP12-3 | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 97/347 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV59970464; called by muse, mutect2, varscan2
- LTF | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 53/289 reads (18%) | catalogued as rs771465834, COSV51613272; called by muse, mutect2, varscan2
- LVRN | c.1314G>T p.E438D | Missense Mutation (SNP) | VAF 84/547 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63497924; called by muse, varscan2
- MAP2K3 | c.479C>A p.T160K (on ENST00000342679 / NM_145109.3; = p.T131K on NM_002756.4) | Missense Mutation (SNP) | VAF 38/506 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.024); catalogued as rs773806671, COSV100384630; called by muse, mutect2
- MUC16 | c.7057G>T p.D2353Y | Missense Mutation (SNP) | VAF 78/227 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV67497638; called by muse, mutect2, varscan2
- MUC5B | c.6893C>A p.P2298H | Missense Mutation (SNP) | VAF 103/353 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV101500889, COSV71590937; called by muse, mutect2, varscan2
- MYO16 | c.4906C>A p.P1636T | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.14); catalogued as rs1346181369; called by muse, mutect2, varscan2
- NEUROD1 | c.720C>A p.F240L | Missense Mutation (SNP) | VAF 101/287 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV54548611; called by muse, mutect2, varscan2
- NOTCH3 | c.5635G>A p.A1879T | Missense Mutation (SNP) | VAF 20/366 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1245481086; called by muse, mutect2
- OR4F6 | c.469G>C p.V157L | Missense Mutation (SNP) | VAF 65/425 reads (15%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.009); catalogued as COSV61027435; called by muse, mutect2, varscan2
- OR8H2 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 77/248 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57944822, COSV57947162; called by muse, mutect2, varscan2
- PHLDB3 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 61/252 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs149990492; called by muse, mutect2, varscan2
- PKD2L2 | c.1756C>A p.Q586K | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as COSV99221142; called by muse, mutect2
- PLCB1 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 82/321 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.387); catalogued as rs368967370; called by muse, mutect2, varscan2
- PPM1L | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 93/329 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV72263328; called by muse, mutect2, varscan2
- PPP4R4 | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 158/402 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58553640; called by muse, mutect2, varscan2
- R3HDM1 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1263603387, COSV51531875; called by muse, mutect2, varscan2
- RAB27A | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 165/714 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.124); catalogued as rs756090505; called by muse, mutect2, varscan2
- RB1 | c.1448A>G p.H483R | Missense Mutation (SNP) | VAF 121/347 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CD133322, CX1414766, COSV57301181; called by muse, mutect2, varscan2
- RTKN2 | c.662G>T p.C221F | Missense Mutation (SNP) | VAF 79/292 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1168310021; called by muse, mutect2, varscan2
- SERPINC1 | c.1142C>G p.S381C | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV62929670; called by muse, mutect2, varscan2
- SIM2 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); catalogued as rs373021150; called by muse, mutect2, varscan2
- SLAMF8 | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56989658; called by muse, varscan2
- SLAMF8 | c.783G>A p.G261= | Splice Region (SNP) | VAF 49/222 reads (22%) | catalogued as COSV56989616; called by muse, varscan2
- SLC25A52 | c.772C>G p.Q258E (on ENST00000672005; = p.Q248E on NM_001034172.4) | Missense Mutation (SNP) | VAF 54/266 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV52501645; called by muse, mutect2, varscan2
- SLC5A6 | c.1106C>G p.S369C | Missense Mutation (SNP) | VAF 73/304 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60161135; called by muse, mutect2, varscan2
- TAF4B | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV52302125; called by muse, mutect2, varscan2
- TFEB | c.245A>G p.Y82C | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1169506393; called by muse, mutect2, varscan2
- TMEM130 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0.225); catalogued as COSV59559911, COSV59560202; called by muse, mutect2, varscan2
- TMEM225 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 111/299 reads (37%) | catalogued as COSV66692915; called by muse, mutect2, varscan2
- TP53 | c.417G>C p.K139N | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV52666570, COSV52937236, COSV53050140; called by muse, mutect2, varscan2
- TRPV6 | c.1513G>A p.V505I | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.314); catalogued as rs369658985; called by muse, mutect2, varscan2
- UNC80 | c.1568G>A p.R523Q | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs1199212965; called by muse, mutect2
- VEGFC | c.223C>G p.P75A | Missense Mutation (SNP) | VAF 69/303 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54600431, COSV99039774; called by muse, mutect2, varscan2
- WNT7A | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.053); catalogued as COSV99541777; called by muse, mutect2, varscan2
- ZNF438 | c.587A>G p.N196S | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs200603286; called by muse, mutect2, varscan2
- ZNF555 | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV62073660; called by muse, mutect2, varscan2
- ABCA12 | c.1783-2A>G p.X595_splice (on ENST00000272895 / NM_173076.3; = p.X277_splice on NM_015657.3) | Splice Site (SNP) | VAF 151/589 reads (26%) | called by muse, mutect2, varscan2
- ADCY6 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ADGRV1 | c.15289G>A p.V5097I | Missense Mutation (SNP) | VAF 174/524 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- AEBP1 | c.705C>A p.Y235* | Nonsense Mutation (SNP) | VAF 26/349 reads (7%) | called by muse, mutect2
- AMPD1 | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 130/716 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.735); called by muse, varscan2
- ANKRD30B | c.3889G>C p.E1297Q | Missense Mutation (SNP) | VAF 250/627 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARHGAP4 | c.2482C>T p.L828F | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASTN1 | c.2948A>C p.Q983P | Missense Mutation (SNP) | VAF 79/245 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- ATP1A1 | c.2473G>C p.E825Q | Missense Mutation (SNP) | VAF 84/324 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ATRIP | c.1496G>T p.G499V | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- BAZ1B | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BRD9 | c.1508C>A p.S503Y | Missense Mutation (SNP) | VAF 182/1821 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2
- CACNA1F | c.2813G>T p.S938I | Missense Mutation (SNP) | VAF 106/185 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CAMSAP3 | c.18_27del p.P7Gfs*8 | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | called by mutect2, pindel, varscan2
- CD300C | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 93/317 reads (29%) | called by muse, mutect2, varscan2
- CDH4 | c.1082C>A p.A361D | Missense Mutation (SNP) | VAF 84/268 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELA2A | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 22/368 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.146); called by muse, mutect2
- CEP250 | c.4606C>A p.Q1536K | Missense Mutation (SNP) | VAF 79/345 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CHD5 | c.686G>T p.S229I | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); called by muse, varscan2
- CLIC6 | c.1292G>C p.R431P | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSF3 | c.293C>A p.P98H | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- CSMD1 | c.415+1G>C p.X139_splice | Splice Site (SNP) | VAF 9/244 reads (4%) | called by muse, mutect2
- DNAH6 | c.8156T>C p.V2719A | Missense Mutation (SNP) | VAF 74/303 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- EFHC2 | c.606G>C p.E202D | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.045); called by mutect2, varscan2
- FAT3 | c.9977C>T p.T3326I | Missense Mutation (SNP) | VAF 134/430 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.441); called by muse, varscan2
- FAT3 | c.10812A>T p.K3604N | Missense Mutation (SNP) | VAF 56/404 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- FLG2 | c.3722G>T p.G1241V | Missense Mutation (SNP) | VAF 88/415 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- FZR1 | c.467A>G p.K156R | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- GALNT17 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | called by muse, varscan2
- GOLGA8Q | c.154C>A p.Q52K | Missense Mutation (SNP) | VAF 88/577 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- GRIA2 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- HGFAC | c.342C>A p.Y114* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- HK3 | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- IGKV1D-16 | c.82C>G p.Q28E | Missense Mutation (SNP) | VAF 149/745 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IL7R | c.819G>T p.W273C | Missense Mutation (SNP) | VAF 292/717 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INPP4B | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 50/219 reads (23%) | called by muse, mutect2, varscan2
- KAT6B | c.2458G>A p.D820N | Missense Mutation (SNP) | VAF 233/838 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KCNG1 | c.915C>A p.D305E | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); called by muse, mutect2
- KCNG4 | c.879del p.L295* | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, varscan2
- KIRREL3 | c.2261C>A p.S754Y | Missense Mutation (SNP) | VAF 48/372 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- LAMA2 | c.2266C>A p.P756T | Missense Mutation (SNP) | VAF 36/592 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); called by muse, mutect2
- LCE3B | c.174C>A p.H58Q | Missense Mutation (SNP) | VAF 173/815 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LCT | c.2641A>G p.K881E | Missense Mutation (SNP) | VAF 76/253 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- LRRC66 | c.903G>T p.R301S | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MAGI1 | c.3477G>C p.E1159D (on ENST00000402939 / NM_001033057.2; = p.E1188D on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- MAP3K19 | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 82/351 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- MASP1 | c.1304T>A p.V435E | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MCM3AP | c.4550-7C>T | Splice Region (SNP) | VAF 92/301 reads (31%) | called by muse, mutect2, varscan2
- MUC17 | c.9580C>A p.P3194T | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- MYO15B | c.5720A>T p.Q1907L | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NEB | c.5104G>C p.E1702Q | Missense Mutation (SNP) | VAF 84/323 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- NRAP | c.3287C>T p.S1096L (on ENST00000359988 / NM_001322945.2; = p.S1061L on NM_006175.4) | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- NUCB1 | c.1303G>C p.A435P | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.497); called by muse, mutect2
- OCSTAMP | c.897T>A p.C299* | Nonsense Mutation (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
- ONECUT2 | c.1319C>A p.T440K | Missense Mutation (SNP) | VAF 19/605 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- OR2H2 | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 109/216 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- OR51B2 | c.425T>A p.L142* | Nonsense Mutation (SNP) | VAF 62/241 reads (26%) | called by muse, mutect2, varscan2
- OR52K1 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 99/442 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- OR5AC2 | c.437T>C p.L146S | Missense Mutation (SNP) | VAF 33/303 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- OR5B3 | c.307G>T p.V103L | Missense Mutation (SNP) | VAF 58/228 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PCDHB13 | c.790A>T p.K264* | Nonsense Mutation (SNP) | VAF 182/600 reads (30%) | called by muse, varscan2
- PCLO | c.14699G>A p.S4900N | Missense Mutation (SNP) | VAF 27/832 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PIAS2 | c.24+1G>A p.X8_splice | Splice Site (SNP) | VAF 24/252 reads (10%) | called by muse, mutect2
- PRDM5 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 25/804 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PRPF8 | c.6423G>C p.E2141D | Missense Mutation (SNP) | VAF 78/310 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSKH2 | c.291A>C p.R97S | Missense Mutation (SNP) | VAF 105/575 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PTCHD1 | c.2358G>T p.W786C | Missense Mutation (SNP) | VAF 98/218 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PXDNL | c.800G>T p.W267L | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- R3HCC1 | c.873G>T p.E291D (on ENST00000411463; = p.E251D on NM_001136108.3) | Missense Mutation (SNP) | VAF 13/265 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.107); called by muse, mutect2
- RB1CC1 | c.1295A>C p.D432A | Missense Mutation (SNP) | VAF 73/301 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- RCC2 | c.303G>T p.K101N | Missense Mutation (SNP) | VAF 141/479 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RNF213 | c.7585A>T p.K2529* | Nonsense Mutation (SNP) | VAF 188/625 reads (30%) | called by muse, mutect2, varscan2
- SARDH | c.1990C>A p.L664M | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- SCFD2 | c.1811T>A p.L604H | Missense Mutation (SNP) | VAF 55/454 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SGSM3 | c.1138G>C p.D380H | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- SIGLEC12 | c.341G>A p.S114N | Missense Mutation (SNP) | VAF 23/562 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2
- SLC19A1 | c.1494G>T p.Q498H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.496); called by muse, mutect2
- SLC6A19 | c.108C>A p.D36E | Missense Mutation (SNP) | VAF 115/2644 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- SLITRK1 | c.148C>G p.L50V | Missense Mutation (SNP) | VAF 61/283 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SLITRK2 | c.1108C>A p.L370M | Missense Mutation (SNP) | VAF 202/318 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMLR1 | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 96/217 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- SMYD3 | c.658C>T p.H220Y (on ENST00000490107 / NM_001375962.1; = p.H161Y on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/416 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- SPPL3 | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 108/388 reads (28%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ST18 | c.1532T>G p.V511G | Missense Mutation (SNP) | VAF 54/360 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- STT3A | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 131/444 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.19); called by muse, varscan2
- SUPT20H | c.511C>T p.Q171* (on ENST00000350612 / NM_001014286.3; = p.Q172* on NM_017569.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 94/282 reads (33%) | called by muse, mutect2, varscan2
- SV2A | c.1104T>A p.D368E | Missense Mutation (SNP) | VAF 38/442 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); called by muse, mutect2
- SVEP1 | c.8510del p.P2837Qfs*8 | Frame Shift Del (DEL) | VAF 87/351 reads (25%) | called by mutect2, pindel, varscan2
- TARM1 | c.94G>A p.G32R (on ENST00000616041 / NM_001330650.1; = p.G24R on NM_001135686.3) | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TCHH | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 36/416 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); called by muse, mutect2
- TECTA | c.4867G>A p.G1623S | Missense Mutation (SNP) | VAF 57/460 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TERF2 | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TIAM1 | c.1834G>T p.E612* | Nonsense Mutation (SNP) | VAF 54/121 reads (45%) | called by muse, mutect2, varscan2
- TMC3 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TMEM207 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 93/426 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TMEM39A | c.292G>T p.V98L | Missense Mutation (SNP) | VAF 124/480 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRPA1 | c.2834C>A p.T945K | Missense Mutation (SNP) | VAF 118/425 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TSHZ3 | c.2182G>T p.V728F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, varscan2
- TTC21B | c.3011A>T p.D1004V | Missense Mutation (SNP) | VAF 189/922 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- TUBA3C | c.768G>T p.Q256H | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- TULP1 | c.1114T>C p.S372P | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP10 | c.1405A>G p.M469V | Missense Mutation (SNP) | VAF 130/536 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- USP53 | c.963_972+3del p.X321_splice | Splice Site (DEL) | VAF 49/202 reads (24%) | called by mutect2, pindel, varscan2
- WSCD1 | c.976G>T p.E326* | Nonsense Mutation (SNP) | VAF 47/112 reads (42%) | called by muse, mutect2, varscan2
- ZEB1 | c.1985C>T p.P662L | Missense Mutation (SNP) | VAF 333/903 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZKSCAN8 | c.1541G>T p.G514V | Missense Mutation (SNP) | VAF 60/282 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF143 | c.1774A>G p.T592A | Missense Mutation (SNP) | VAF 66/674 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- ZNF185 | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF423 | c.2062C>G p.H688D (on ENST00000563137 / NM_001379286.1; = p.H680D on NM_015069.4) | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF479 | c.353G>T p.C118F | Missense Mutation (SNP) | VAF 183/596 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ZNF583 | c.1383A>T p.E461D | Missense Mutation (SNP) | VAF 42/592 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- ZNF629 | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 15/385 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2
- ZNF667 | c.1005T>A p.C335* | Nonsense Mutation (SNP) | VAF 64/289 reads (22%) | called by muse, mutect2, varscan2
- ZNF816 | c.1328A>T p.H443L | Missense Mutation (SNP) | VAF 109/402 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCA13 | c.6303T>C p.F2101= | Silent (SNP) | VAF 188/684 reads (27%) | called by muse, mutect2, varscan2
- ABCC9 | c.2811C>G p.L937= | Silent (SNP) | VAF 106/828 reads (13%) | called by muse, mutect2, varscan2
- AHNAK2 | c.6669G>A p.E2223= | Silent (SNP) | VAF 102/381 reads (27%) | called by muse, varscan2
- AP1M2 | c.99C>T p.F33= | Silent (SNP) | VAF 32/186 reads (17%) | catalogued as COSV51569254; called by muse, mutect2, varscan2
- APH1A | c.54C>T p.F18= | Silent (SNP) | VAF 30/370 reads (8%) | catalogued as rs782165938, COSV52528202; called by muse, mutect2
- ASXL2 | c.1911T>C p.S637= | Silent (SNP) | VAF 48/150 reads (32%) | called by mutect2, varscan2
- BIN1 | c.1743T>C p.R581= (on ENST00000316724 / NM_001320642.1; = p.R442= on NM_004305.4) | Silent (SNP) | VAF 76/340 reads (22%) | called by muse, mutect2, varscan2
- BRD9 | c.1459C>T p.L487= | Silent (SNP) | VAF 183/2050 reads (9%) | called by muse, mutect2
- C3 | c.3177C>T p.F1059= | Silent (SNP) | VAF 53/508 reads (10%) | called by muse, mutect2, varscan2
- C8orf34 | c.573T>C p.S191= | Silent (SNP) | VAF 33/449 reads (7%) | called by muse, mutect2
- CDC37L1 | c.43C>A p.R15= | Silent (SNP) | VAF 50/206 reads (24%) | catalogued as rs757309428, COSV101116447; called by muse, mutect2, varscan2
- CDH4 | c.1083C>A p.A361= | Silent (SNP) | VAF 87/272 reads (32%) | called by muse, mutect2, varscan2
- CDS2 | c.921G>C p.S307= | Silent (SNP) | VAF 61/305 reads (20%) | catalogued as COSV100986059; called by muse, mutect2, varscan2
- CLVS1 | c.573C>T p.F191= | Silent (SNP) | VAF 41/217 reads (19%) | called by muse, mutect2, varscan2
- CYLC2 | c.132A>C p.G44= | Silent (SNP) | VAF 139/591 reads (24%) | called by muse, mutect2, varscan2
- DEFB118 | c.177T>C p.N59= | Silent (SNP) | VAF 124/640 reads (19%) | called by muse, mutect2, varscan2
- DNAH9 | c.6756C>T p.S2252= | Silent (SNP) | VAF 12/134 reads (9%) | called by muse, mutect2
- DPY19L4 | c.1242G>T p.L414= | Silent (SNP) | VAF 22/663 reads (3%) | called by muse, mutect2
- FAT1 | c.4755G>T p.T1585= | Silent (SNP) | VAF 149/582 reads (26%) | called by muse, mutect2, varscan2
- FGA | c.1395T>A p.V465= | Silent (SNP) | VAF 52/210 reads (25%) | called by muse, mutect2, varscan2
- GBP3 | c.1689C>T p.C563= | Silent (SNP) | VAF 54/262 reads (21%) | catalogued as rs370105248; called by muse, varscan2
- GOLGA8M | c.1659T>C p.S553= | Silent (SNP) | VAF 126/638 reads (20%) | called by muse, mutect2, varscan2
- HAPLN4 | c.630C>T p.N210= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as rs771835797, COSV52269416, COSV52270158; called by muse, mutect2, varscan2
- HIVEP2 | c.645G>A p.R215= | Silent (SNP) | VAF 77/317 reads (24%) | called by muse, mutect2, varscan2
- HUWE1 | c.11949T>C p.A3983= | Silent (SNP) | VAF 127/223 reads (57%) | called by muse, mutect2, varscan2
- IGKV2-24 | c.27G>T p.G9= | Silent (SNP) | VAF 81/388 reads (21%) | catalogued as rs774665686; called by muse, mutect2, varscan2
- KANK1 | c.711C>T p.S237= | Silent (SNP) | VAF 14/152 reads (9%) | called by muse, mutect2
- MED17 | c.147C>T p.F49= | Silent (SNP) | VAF 58/205 reads (28%) | called by muse, mutect2, varscan2
- NLRP7 | c.1368G>A p.Q456= | Silent (SNP) | VAF 48/147 reads (33%) | called by muse, mutect2, varscan2
- NPL | c.402C>T p.A134= | Silent (SNP) | VAF 151/807 reads (19%) | catalogued as rs777069833, COSV51128884; called by muse, mutect2, varscan2
- NUP205 | c.3663A>G p.L1221= | Silent (SNP) | VAF 123/356 reads (35%) | called by muse, mutect2, varscan2
- ORAI3 | c.147C>T p.L49= | Silent (SNP) | VAF 32/169 reads (19%) | catalogued as rs1258375574; called by muse, mutect2, varscan2
- PCNX3 | c.1437T>G p.A479= | Silent (SNP) | VAF 57/176 reads (32%) | called by muse, mutect2, varscan2
- PLB1 | c.3585C>T p.I1195= | Silent (SNP) | VAF 49/205 reads (24%) | called by muse, mutect2, varscan2
- PNLIPRP1 | c.1296G>A p.V432= | Silent (SNP) | VAF 26/181 reads (14%) | catalogued as rs374698455, COSV100724472; called by muse, mutect2, varscan2
- POLR1E | c.1401A>G p.P467= (on ENST00000377792 / NM_001282766.1; = p.P405= on NM_022490.4) | Silent (SNP) | VAF 22/118 reads (19%) | called by muse, mutect2, varscan2
- PPP2R5C | c.153C>T p.V51= | Silent (SNP) | VAF 143/1015 reads (14%) | catalogued as rs760394486; called by muse, mutect2, varscan2
- PSMA1 | c.144A>G p.A48= | Silent (SNP) | VAF 50/151 reads (33%) | called by muse, mutect2, varscan2
- RELN | c.6168C>A p.P2056= | Silent (SNP) | VAF 49/706 reads (7%) | catalogued as COSV58998203; called by muse, mutect2
- SLC6A6 | c.1266A>C p.L422= | Silent (SNP) | VAF 65/180 reads (36%) | called by muse, mutect2, varscan2
- SVEP1 | c.5214C>A p.G1738= | Silent (SNP) | VAF 52/162 reads (32%) | called by muse, mutect2, varscan2
- TBC1D13 | c.456G>A p.Q152= | Silent (SNP) | VAF 55/232 reads (24%) | catalogued as COSV99804619; called by muse, mutect2, varscan2
- TRAV2 | c.174C>T p.F58= | Silent (SNP) | VAF 128/831 reads (15%) | called by muse, varscan2
- TTBK2 | c.1866A>T p.A622= | Silent (SNP) | VAF 18/430 reads (4%) | called by muse, mutect2
- UBA6 | c.186C>T p.S62= | Silent (SNP) | VAF 22/690 reads (3%) | catalogued as rs1392706902; called by muse, mutect2
- VCAN | c.3582A>C p.I1194= | Silent (SNP) | VAF 71/199 reads (36%) | called by muse, mutect2, varscan2
- VWF | c.5406C>T p.D1802= | Silent (SNP) | VAF 106/576 reads (18%) | catalogued as rs565224789, COSV99778577; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR61 | c.414G>T p.G138= | Silent (SNP) | VAF 74/324 reads (23%) | called by mutect2, varscan2
- ZNF559-ZNF177 | c.858C>T p.H286= | Silent (SNP) | VAF 15/430 reads (3%) | called by muse, mutect2
- ZP4 | c.117C>T p.F39= | Silent (SNP) | VAF 58/206 reads (28%) | catalogued as COSV63913583; called by muse, mutect2, varscan2
- ARMCX4 | c.1038+968G>T | Intron (SNP) | VAF 27/44 reads (61%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56811820 G>T | 3'Flank (SNP) | VAF 27/258 reads (10%) | called by muse, mutect2
- DUX4L4 | n.1057C>A | RNA (SNP) | VAF 30/622 reads (5%) | catalogued as rs1553975586; called by muse, mutect2
- EOMES | c.1380-40A>G | Intron (SNP) | VAF 23/78 reads (29%) | called by muse, varscan2
- GORAB | c.*620C>T | 3'UTR (SNP) | VAF 69/372 reads (19%) | catalogued as rs764522922; called by muse, mutect2, varscan2
- LRRTM4 | c.-36C>A | 5'UTR (SNP) | VAF 103/368 reads (28%) | catalogued as COSV69138778; called by muse, mutect2, varscan2
- LY6K | c.-17G>T | 5'UTR (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- MKRN9P | n.201G>T | RNA (SNP) | VAF 110/283 reads (39%) | called by muse, mutect2, varscan2
- MUC2 | chr11:1094455 C>A | 3'Flank (SNP) | VAF 49/161 reads (30%) | called by muse, mutect2, varscan2
- MYADML | n.949C>A | RNA (SNP) | VAF 44/192 reads (23%) | called by muse, mutect2, varscan2
- MYADML | n.948C>A | RNA (SNP) | VAF 45/196 reads (23%) | called by muse, mutect2, varscan2
- NMRK2 | c.-44C>A | 5'UTR (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- PHPT1 | c.285+27C>T | Intron (SNP) | VAF 18/140 reads (13%) | catalogued as rs1184133968; called by muse, mutect2, varscan2
- PLEKHM1 | c.1580-45G>A | Intron (SNP) | VAF 14/198 reads (7%) | catalogued as rs781018940; called by muse, mutect2
- PLEKHM1 | c.1580-47G>A | Intron (SNP) | VAF 13/186 reads (7%) | called by muse, mutect2
- POLR1B | chr2:112542175 C>A | 5'Flank (SNP) | VAF 78/380 reads (21%) | called by muse, mutect2, varscan2
- PRICKLE1 | c.*461C>G | 3'UTR (SNP) | VAF 20/274 reads (7%) | called by muse, mutect2
- SELENBP1 | c.-47C>T | 5'UTR (SNP) | VAF 26/298 reads (9%) | catalogued as COSV100923620; called by muse, mutect2
- SLC23A3 | c.492+12G>T | Intron (SNP) | VAF 54/201 reads (27%) | called by muse, mutect2, varscan2
- SLC6A13 | c.479-313G>A | Intron (SNP) | VAF 41/431 reads (10%) | catalogued as rs748502738; called by muse, mutect2
- SNORA60 | n.47A>G | RNA (SNP) | VAF 101/340 reads (30%) | catalogued as rs1241226139; called by muse, mutect2, varscan2
- SSU72 | chr1:1575148 G>C | 5'Flank (SNP) | VAF 89/379 reads (23%) | called by muse, mutect2, varscan2
- TCP10L3 | n.2727C>A | RNA (SNP) | VAF 16/292 reads (5%) | called by muse, mutect2
- TMEM40 | c.425-69C>A | Intron (SNP) | VAF 73/237 reads (31%) | called by muse, mutect2, varscan2
- UGT2A1 | c.715+11179G>T | Intron (SNP) | VAF 9/61 reads (15%) | catalogued as rs1010538730, COSV54144344; called by muse, mutect2, varscan2
- USH1C | c.1284+7609C>A | Intron (SNP) | VAF 33/104 reads (32%) | catalogued as COSV50038332; called by muse, mutect2, varscan2
- XIST | n.8517G>C | RNA (SNP) | VAF 24/182 reads (13%) | called by muse, mutect2, varscan2
- XXYLT1 | c.505-20962C>T | Intron (SNP) | VAF 47/242 reads (19%) | called by muse, mutect2, varscan2
